Somatic mutation profile of tumor specimen MP2PRT-PASZAC-TMP1-B (aliquot MP2PRT-PASZAC-TMP1-B-1-0-D-A817-36) from MP2PRT case MP2PRT-PASZAC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,803 days).
Specimen MP2PRT-PASZAC-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e97a0c74-ba0c-44fe-8ed4-d614b4d43420.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASZAC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASZAC-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c656ad6-ff7a-4257-8466-5bc119b1a2fa

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NTNG2 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 62/1014 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.503); catalogued as COSV62369366; called by muse, mutect2
- PGAP4 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 205/496 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1187517409, COSV100877888; called by muse, mutect2, varscan2
- XRN2 | c.1844G>A p.R615Q | Missense Mutation (SNP) | VAF 69/257 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as rs376273044; called by muse, mutect2, varscan2
- BICC1 | c.1753T>C p.S585P | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.261); called by muse, mutect2
- CELSR2 | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 186/482 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP4R3C | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 150/164 reads (91%) | called by muse, mutect2, varscan2
- CCDC102B | c.1152G>A p.K384= | Silent (SNP) | VAF 127/286 reads (44%) | catalogued as COSV60136739; called by muse, mutect2, varscan2
- JAML | c.759G>A p.P253= (on ENST00000356289 / NM_001098526.2; = p.P243= on NM_153206.3) | Silent (SNP) | VAF 104/258 reads (40%) | catalogued as rs747718995, COSV52628628; called by muse, mutect2, varscan2
- LNX2 | c.552C>T p.G184= | Silent (SNP) | VAF 217/487 reads (45%) | catalogued as rs778168392, COSV60337279; called by muse, mutect2, varscan2
- MSX2 | c.441G>A p.T147= | Silent (SNP) | VAF 55/519 reads (11%) | catalogued as rs780693712; called by muse, mutect2, varscan2
